Surgical pathology report (de-identified scan), TCGA case TCGA-HD-A4C1, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-HD-A4C1-01A (Primary Tumor).

[page 1 of 4]
Addendum Report Surgical

* Final Report *

Result Type: Addendum Report Surgical
Result Date:
Result Status: Auth (Verified)
Result Title: Addendum Report
Verified By:
Encounter info:

. inal Report *

Addendum (Verified)
Special immunoperoxidase stains for p16 (surrogate marker for HPV) performed on slides A1 and A11 are negative.

Testing performed at

Signature Line

(Electronically signed by)

Completed Action List:

1CD-0-3
carcinoma, squamous cell NOS
807013
Site: breast mucosa col.0
9/27/12

[page 2 of 4]
Surg Path Final Report

* Final Report *

Right level 4, lymph nodes:
Six negative lymph nodes.

Right level 2, lymph nodes:
Two negative lymph nodes.

Right level 3, lymph nodes:
Ten negative lymph nodes.

AJCC pathologic stage T4a,N2b.

Comment: Special immunoperoxidase stain for p16 on selected slides will be performed and an addendum report submitted.

Signature Line

(Electronically signed by)
Verified on:

Performing Lab (Verified)

Testing performed at

Gross Description (Verified)

"A, Composite resection left hemimandible lip facial skin, left submental triangle contents." The specimen consists of a left hemimandible and teeth, lip, facial skin and surrounding yellow-tan, fatty tissue. This has an overall measurement of 11.9 x 7.4 x 8.2 cm. The specimen is inked as follows: anterior soft tissue margin blue, posterior soft tissue margin and posterior mandibular bone margin black, medial margin yellow, medial mandibular bone margin red, superior soft tissue margin orange and inferior soft tissue margin green. Attached to the lateral aspect of the specimen is a 9.8 x 7.9 cm tan-brown skin fragment involving the central portion of the skin is a gray-tan, ragged, roughened and ulcerated appearing lesion which measures 6.2 x 5.5 cm. Within the palate and involving the surrounding mucosa is a gray-tan, soft, ulcerated mass which measures 5.6 x 5.8 x 5.2 cm. This mass grossly appears to abut the lateral and inferior soft tissue margins and appears to be continuous with the ulcerated area on the palate.

[page 3 of 4]
Surg Path Final Report

* Final Report *

appears to extend through the attached skin at the lateral aspect correlating with the ragged, roughened skin lesion. The lateral and posterior mandibular bone margins grossly appear to be free. On sectioning of the posterior soft tissue margin, a 3.3 x 1.8 x 2.2 cm yellow-tan, lobulated, slightly firm fragment is identified. This appears grossly unremarkable. There are also 3 pale tan possible lymph nodes. These range in size from 0.6 to 1.1 cm. The attached teeth are gray-white to gold-plated and unremarkable. "A1," mass to include central mandible, medial soft tissue margin and inferior soft tissue margin; "A2," mass to include medial and inferior soft tissue margins; "A3-A4," mass to include inferior soft tissue margin; "A5," mass to include superior soft tissue margin; "A6," mass to include inferior and posterior soft tissue margins; "A7," mass to include posterior margin; "A8," mass to include anterior soft tissue and skin margin; "A9," mass to include inferior soft tissue and skin margin; "A10," mass to include superior soft tissue and skin margin; "A11," central portion of skin to include lesion; "A12," medial and posterior mandibular bone margins; "A13," yellow-tan, firm, lobulated fragment involving posterior soft tissue; "A14," possible lymph nodes, representative. NOTE: Please see attached drawing.

"B, Left level 2." The specimen consists of a 6.5 x 3.5 x 1.9 cm yellow-brown, firm, fatty fragment. On examination, 5 possible lymph nodes are identified. These range in size from 0.7 to 5.4 cm. Representative sections are submitted into cassettes "B1-B2." "B1," smaller lymph nodes; "B2," largest lymph node, representative.

"C, Left level 3." The specimen consists of a 6.9 x 3.8 x 2.5 cm yellow-brown, firm, fatty fragment. On examination, 12 possible lymph nodes are identified. These range in size from 0.3 to 2.0 cm. "C1-C2," possible lymph nodes, representative.

"D, Left level 4." The specimen consists of a 3.5 x 2.4 x 1.4 cm yellow-brown, firm, fatty fragment. On examination, a 2.3 cm possible lymph node is identified. A representative section is submitted into cassette "D."

"E, 1A." The specimen consists of a 4.3 x 4.5 x 2.5 cm yellow-brown, firm, fatty fragment. On examination, 4 pale to mucus-appearing possible lymph nodes are identified. These range in size from 0.7 to 2.0 cm. The remaining cut surface is tan-brown and firm to yellow-tan and fatty. Representative sections of the possible lymph nodes are submitted into cassettes "E1-E2."

"F, Right level 1B." The specimen consists of a 4.7 x 3.4 x 2.5 cm yellow-brown, firm, fatty fragment. On examination, 3 possible lymph nodes are identified. These range in size from 1.1 to 1.6 cm. There is also a 4.5 x 1.9 x 1.5 cm yellow-brown, firm, lobulated fragment. "F1," possible lymph nodes; "F2," yellow-brown, firm, lobulated fragment, representative.

"G, Right level 4." The specimen consists of 3 yellow-brown, fatty fragments ranging in size from 1.5 to 3.9 cm. On examination, 6 possible lymph nodes are identified. These range in size from 0.2 to 0.6 cm. "G1-G2," possible lymph nodes, representative.

"H, Right level 2." The specimen consists of 2 yellow-brown, fatty fragments measuring 1.2 and 4.0 cm. On examination, 2 possible lymph nodes are identified. These measure 1.0 and 3.0 cm. Representative sections are submitted into cassette "H."

"I, Right level 3." The specimen consists of a 5.8 x 4.5 x 1.7 cm yellow-brown, firm fatty fragment. On examination, 12 possible lymph nodes are identified. These range in size from 0.3 to 1.6 cm. Representative sections are submitted into cassettes "I1-I2."

Signature Line

Clinical Information (Verified)

Facial squamous cell carcinoma.

Completed Action List:

[page 4 of 4]
Surg Path Final Report

* Final Report *

Result Type: Surg Path Final Report
Result Date:
Result Status: Auth (Verified)
Result Title: Surgical Pathology Final Report
Verified By:
Encounter info:

Final Report *

Final Diagnosis (Verified)

Composite resection left hemimandible, lip, facial skin, left submental triangle:

Well differentiated infiltrating squamous cell carcinoma.

Tumor involves left buccal mucosa with involvement of the mandible and erosion through the skin.

Tumor mass measures 6.6 cm in greatest dimension.

Tumor focality: Single focus.

Margins: All margins are free of tumor. The closest surgical margin is the inferior margin (green) which is 2 mm.

No overt lymphovascular invasion is noted.

No overt perineural invasion is noted.

Level 2, lymph nodes:

Metastatic squamous cell carcinoma in 2 of 5 lymph nodes.

Level 3, lymph nodes:

Metastatic squamous cell carcinoma in 2 of 11 lymph nodes.

Level 4, lymph nodes:

One negative lymph node.

Level 1a, lymph nodes:

Metastatic squamous cell carcinoma in 3 of 4 lymph nodes.

Right level 1b, lymph nodes:

Three negative lymph nodes

Criteria	
Diagnostic Discrepancy	Yes
Level 1a	QUALIFIED
Level 2	QUALIFIED
Level 3	QUALIFIED
Level 4	QUALIFIED
Level 1b	QUALIFIED

9/4/12 lw

Source: NCI Genomic Data Commons file 92aac392-71f1-4f51-b68e-faa23afe32b3 (TCGA-HD-A4C1.CBE8741B-8976-4F97-B413-9AE3B41790E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).